Somatic mutation profile of tumor specimen TCGA-IG-A6QS-01A (aliquot TCGA-IG-A6QS-01A-12D-A33E-09) from TCGA case TCGA-IG-A6QS, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 54.5 years (19,900 days).
Specimen TCGA-IG-A6QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 236e1e95-37ec-4cf5-a77f-ccbf4ba074cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A6QS-10B (Blood Derived Normal), aliquot TCGA-IG-A6QS-10B-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81ab2fdd-ccd0-4b21-b89f-c9ad55e5afa3

The open-access MAF lists 66 somatic variants for this specimen: 47 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Frame Shift Del 2, Intron 2, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 38/46 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP13 | c.8428G>C p.E2810Q (on ENST00000394518 / NM_007200.5; = p.E2814Q on NM_006738.6) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63465816; called by muse, mutect2, varscan2
- C2orf42 | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.417); catalogued as COSV100034122; called by muse, mutect2, varscan2
- CCT8 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV54505844; called by muse, mutect2, varscan2
- DGKK | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 24/39 reads (62%) | catalogued as rs370221683, COSV101052889; called by muse, mutect2, varscan2
- DHX57 | c.320A>T p.N107I | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV99769731; called by muse, mutect2, varscan2
- GPCPD1 | c.1157A>T p.D386V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs1410066959; called by muse, mutect2, varscan2
- L2HGDH | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV99910600; called by muse, mutect2
- MEGF11 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as rs1459509635; called by muse, mutect2
- MICU1 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV63143498; called by muse, mutect2, varscan2
- OR52B4 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs1206370820; called by muse, mutect2, varscan2
- PCLO | c.4102G>A p.D1368N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs533061339, COSV61638785, COSV61659459; called by muse, mutect2, varscan2
- PFKFB2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | PolyPhen possibly damaging (0.894); catalogued as rs757942412, COSV65547271; called by muse, mutect2, varscan2
- SMARCA4 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); catalogued as rs1240479086; called by muse, mutect2, varscan2
- TLN2 | c.4850G>A p.R1617H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs776245129, COSV60888748; called by muse, mutect2, varscan2
- TOB2 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs776245257; called by muse, mutect2, varscan2
- ZNF878 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.472); catalogued as COSV101521174, COSV72156121; called by muse, mutect2, varscan2
- ACACA | c.6904G>A p.D2302N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ADRA1A | c.1284C>G p.S428R | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ANKAR | c.1708+2T>C p.X570_splice | Splice Site (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- AUNIP | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- BAZ2B | c.4427C>T p.A1476V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- BCL11A | c.612T>G p.F204L (on ENST00000335712 / NM_001365609.1; = p.F238L on NM_018014.4) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- BRINP1 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CC2D1A | c.2428G>C p.D810H | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTTNBP2 | c.4110A>G p.I1370M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- CWC22 | c.2354C>T p.T785I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CWH43 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- CYP4F22 | c.1213G>T p.V405F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- DIAPH2 | c.2638A>G p.I880V | Missense Mutation (SNP) | VAF 144/172 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM160A2 | c.1988G>A p.G663D (on ENST00000449352 / NM_001098794.2; = p.G677D on NM_032127.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT12 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 128/150 reads (85%) | SIFT tolerated (0.74); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GEN1 | c.2608del p.S870Qfs*6 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | called by mutect2, pindel, varscan2
- ITGB1BP2 | c.565A>T p.I189F | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NOLC1 | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- PCNX1 | c.3853T>A p.F1285I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PNMA8A | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- RAPGEF4 | c.2579T>G p.L860R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC9A4 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SUPT16H | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYNJ1 | c.2041del p.I681Sfs*17 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | called by mutect2, pindel, varscan2
- TIGD7 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- TOE1 | c.1447G>C p.V483L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TRIP11 | c.2148G>A p.M716I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPC5 | c.1730G>C p.W577S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VCL | c.2041A>G p.I681V | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ZNF496 | c.931A>G p.R311G | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- AUNIP | c.1014G>A p.K338= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- CFAP58 | c.1330C>A p.R444= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV57211816; called by muse, mutect2, varscan2
- CLDN10 | c.681T>C p.Y227= | Silent (SNP) | VAF 30/49 reads (61%) | called by muse, mutect2, varscan2
- EIF4G3 | c.714C>T p.V238= | Silent (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- JMY | c.1104C>A p.A368= | Silent (SNP) | VAF 36/51 reads (71%) | called by muse, mutect2, varscan2
- KATNB1 | c.1794G>A p.A598= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs781829852; called by muse, mutect2, varscan2
- LPAR3 | c.1041C>T p.V347= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- LRP5 | c.2643C>G p.L881= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- OR11L1 | c.874T>C p.L292= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- SCN7A | c.669G>A p.L223= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs1186146811, COSV69274571; called by muse, mutect2, varscan2
- SDK1 | c.2553C>T p.A851= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs562967510, COSV67376410; called by muse, mutect2, varscan2
- SPRY1 | c.651A>G p.E217= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- SRPX2 | c.570T>G p.R190= | Silent (SNP) | VAF 54/61 reads (89%) | called by muse, mutect2, varscan2
- TRAV34 | c.75G>A p.E25= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs1395200324; called by muse, mutect2, varscan2
- TRPM3 | c.1776C>T p.R592= (on ENST00000357533 / NM_001366142.2; = p.R425= on NM_020952.6) | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- USP1 | c.1950A>T p.G650= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- EXT2 | c.1173+14115A>G | Intron (SNP) | VAF 27/74 reads (36%) | catalogued as rs747999174, COSV59148609; called by muse, mutect2, varscan2
- ITGA7 | c.3316-959C>T | Intron (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- MIR517B | n.61G>A | RNA (SNP) | VAF 64/125 reads (51%) | catalogued as rs1401655512; called by muse, mutect2, varscan2
